Somatic mutation profile of tumor specimen TCGA-BM-6198-01A (aliquot TCGA-BM-6198-01A-11D-1733-10) from TCGA case TCGA-BM-6198, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 73.5 years (26,837 days).
Specimen TCGA-BM-6198-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55328dc6-a2a4-4444-92c0-111a368b0359.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BM-6198-10A (Blood Derived Normal), aliquot TCGA-BM-6198-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4caeeb15-c1a7-4d2b-b144-fa698451962e

The open-access MAF lists 135 somatic variants for this specimen: 102 protein-altering or splice-affecting, 32 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 32, Splice Site 5, Frame Shift Del 5, Nonsense Mutation 4, Frame Shift Ins 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AVP | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906511, CM930061, COSV66672097; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F13A1 | c.2110C>T p.R704W | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267606787, CM093521, COSV53565534; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 20/63 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.1800G>T p.Q600H (on ENST00000614293; = p.Q570H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV55805591, COSV99686900; called by muse, mutect2, varscan2
- ADAM21 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs1280217034, COSV50805729; called by muse, mutect2, varscan2
- ADAM33 | c.670T>A p.L224M | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV62936542; called by muse, mutect2, varscan2
- AGAP2 | c.3020C>T p.A1007V (on ENST00000547588 / NM_001122772.2; = p.A651V on NM_014770.4) | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as COSV57731003; called by muse, mutect2, varscan2
- AKT2 | c.46+1G>C p.X16_splice | Splice Site (SNP) | VAF 17/58 reads (29%) | catalogued as COSV60910042; called by muse, mutect2, varscan2
- BDKRB2 | c.385C>T p.L129F | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60016632; called by muse, mutect2, varscan2
- C2orf78 | c.946A>C p.S316R | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as rs760602222, COSV68519042; called by muse, mutect2, varscan2
- CHST3 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.115); catalogued as COSV64151625; called by muse, mutect2, varscan2
- CLEC4G | c.875A>T p.N292I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV61002814, COSV61004000; called by muse, mutect2, varscan2
- COL13A1 | c.361C>G p.P121A | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV62573912; called by muse, mutect2, varscan2
- COL19A1 | c.3002G>T p.G1001V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100505770; called by muse, mutect2
- CPNE3 | c.1467T>A p.F489L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769586297, COSV52209538; called by muse, mutect2, varscan2
- CSMD3 | c.3473G>A p.R1158H (on ENST00000297405 / NM_001363185.1; = p.R1054H on NM_052900.3) | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756700595, COSV52095387; called by muse, mutect2, varscan2
- CYP4B1 | c.977G>T p.W326L | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs755652341, COSV54725530; called by muse, mutect2, varscan2
- DLGAP4 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs762577016, COSV59422245; called by muse, mutect2, varscan2
- DNPEP | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV56110762; called by muse, mutect2, varscan2
- DPP10 | c.308T>A p.V103D | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59716204; called by muse, mutect2, varscan2
- DSEL | c.761G>C p.G254A | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.304); catalogued as COSV59493986; called by muse, mutect2, varscan2
- DYNC1I1 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs756202767, COSV61469216; called by muse, varscan2
- EPC2 | c.2063G>A p.S688N | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV51546974, COSV51548360; called by muse, mutect2, varscan2
- ESPNL | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779749767, COSV58037520; called by muse, mutect2, varscan2
- EYA1 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.469); catalogued as COSV58171776; called by muse, mutect2, varscan2
- FAH | c.290G>T p.R97I | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV55723304; called by muse, varscan2
- FAM83E | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370573825; called by muse, mutect2
- FBN3 | c.7849C>T p.R2617W | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.967); catalogued as rs201196689, COSV54461815; called by muse, mutect2, varscan2
- FCGBP | c.9524C>T p.T3175M | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs764454718; called by muse, mutect2, varscan2
- GLI1 | c.2535G>T p.Q845H | Missense Mutation (SNP) | VAF 74/139 reads (53%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV57366016; called by muse, mutect2, varscan2
- HCN3 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 56/237 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64235012; called by muse, mutect2, varscan2
- HK3 | c.1133C>A p.A378D | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV52843593; called by muse, mutect2, varscan2
- HYDIN | c.5987T>C p.I1996T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1159831690, COSV99992345; called by muse, mutect2, varscan2
- IFNL2 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs373827690; called by muse, mutect2, varscan2
- INPP4B | c.1720+2T>A p.X574_splice | Splice Site (SNP) | VAF 46/114 reads (40%) | catalogued as COSV99523579; called by muse, varscan2
- INTS11 | c.1326G>C p.E442D | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as COSV60090066; called by muse, mutect2
- ITGAX | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99191552; called by muse, mutect2
- KALRN | c.3135C>G p.I1045M | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV53772575, COSV53777040; called by muse, mutect2, varscan2
- KBTBD6 | c.982G>T p.V328L | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101068737; called by muse, mutect2, varscan2
- KBTBD7 | c.982G>T p.V328L | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1444417401, COSV101068064; called by muse, mutect2, varscan2
- KIF21A | c.2881C>T p.R961* (on ENST00000361418 / NM_001378440.1; = p.R948* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 119/568 reads (21%) | catalogued as rs142292357; called by muse, mutect2, varscan2
- KIF26B | c.3373C>T p.R1125C | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs930866001, COSV63640080; called by muse, mutect2, varscan2
- KLHL20 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 95/212 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.422); catalogued as COSV52944498; called by muse, mutect2, varscan2
- KLHL38 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as rs778497066, COSV58088741; called by muse, mutect2, varscan2
- LAMB1 | c.4091A>T p.E1364V | Missense Mutation (SNP) | VAF 109/310 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV55969205; called by muse, mutect2, varscan2
- LAPTM4B | c.511C>G p.L171V (on ENST00000445593; = p.L80V on NM_018407.6) | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV71454766; called by muse, mutect2, varscan2
- LATS2 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565941238, COSV66878584; called by muse, mutect2, varscan2
- LILRB1 | c.521G>T p.G174V (on ENST00000427581; = p.G138V on NM_006669.6) | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61115620, COSV61121103; called by muse, varscan2
- LRP1 | c.1392C>G p.I464M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV54522822; called by muse, mutect2, varscan2
- MAPK15 | c.620T>A p.I207N | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62029799; called by muse, mutect2, varscan2
- MCM3AP | c.2330del p.E777Gfs*3 | Frame Shift Del (DEL) | VAF 40/160 reads (25%) | catalogued as COSV52444507; called by mutect2, pindel, varscan2
- MDN1 | c.9035T>C p.L3012S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65528639; called by muse, mutect2, varscan2
- MYO1G | c.304+1G>A p.X102_splice | Splice Site (SNP) | VAF 25/62 reads (40%) | catalogued as COSV51856605; called by muse, mutect2, varscan2
- NAP1L1 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs1290646596, COSV53876224; called by muse, mutect2, varscan2
- NAV2 | c.5527T>A p.F1843I (on ENST00000396087 / NM_001244963.2; = p.F1784I on NM_145117.5) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60664100; called by muse, mutect2, varscan2
- NCOR1 | c.5572G>T p.A1858S | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.084); catalogued as COSV51991387; called by muse, mutect2, varscan2
- NEB | c.13931A>G p.N4644S | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV51451477; called by muse, mutect2, varscan2
- NKAPL | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV59197591, COSV59197802; called by muse, mutect2, varscan2
- NODAL | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54661441; called by muse, mutect2, varscan2
- NPHP4 | c.1136C>G p.S379C | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV65397150; called by muse, mutect2, varscan2
- OR52A1 | c.839C>G p.S280C | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100200530, COSV61093128; called by muse, mutect2, varscan2
- OSR2 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.056); catalogued as COSV99882410; called by muse, mutect2, varscan2
- PAIP1 | c.340G>C p.A114P | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as COSV59087204; called by muse, mutect2, varscan2
- PARD6B | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV65405133; called by muse, mutect2, varscan2
- PCDHA4 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100793260; called by muse, mutect2
- PCDHGB3 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV53920507; called by muse, mutect2, varscan2
- PCGF6 | c.940G>C p.E314Q (on ENST00000369847 / NM_001011663.2; = p.E239Q on NM_032154.4) | Missense Mutation (SNP) | VAF 107/179 reads (60%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.879); catalogued as COSV61495884; called by muse, mutect2, varscan2
- PCNX1 | c.4286T>C p.F1429S | Missense Mutation (SNP) | VAF 124/293 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.176); catalogued as rs747236461, COSV53100289; called by muse, mutect2, varscan2
- PHACTR1 | c.630G>C p.E210D | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.899); catalogued as COSV60667559, COSV60678622; called by muse, mutect2, varscan2
- PLA2G4F | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs776310395, COSV51829024; called by muse, mutect2, varscan2
- PLEC | c.11012C>A p.P3671H (on ENST00000322810 / NM_201380.4; = p.P3561H on NM_000445.5) | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100520167, COSV59683815; called by muse, mutect2
- PROZ | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as rs1357525220, COSV100720300; called by muse, mutect2, varscan2
- RESF1 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV100440234; called by muse, mutect2, varscan2
- SCN11A | c.2170G>T p.G724C | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56576497; called by muse, mutect2, varscan2
- SCN11A | c.2169T>G p.F723L | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.471); catalogued as COSV56576505; called by muse, mutect2, varscan2
- SFXN5 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.084); catalogued as rs1192524406, COSV50256004; called by muse, mutect2, varscan2
- SOX14 | c.542G>C p.S181T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as COSV60163353; called by muse, mutect2, varscan2
- STK11IP | c.413G>A p.C138Y | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55254473; called by muse, mutect2, varscan2
- SYNJ1 | c.4306A>T p.I1436F | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as COSV100449112; called by muse, mutect2, varscan2
- TAGLN3 | c.48G>C p.E16D | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV56329201; called by muse, mutect2, varscan2
- TAOK1 | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.838); catalogued as COSV55597419; called by muse, mutect2, varscan2
- TCF3 | c.470C>A p.S157Y | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV53652655; called by muse, mutect2, varscan2
- TDRD6 | c.6267G>C p.R2089S | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.027); catalogued as COSV99221226; called by muse, mutect2, varscan2
- TFR2 | c.1987G>A p.D663N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs1260887893, COSV56156114; called by muse, mutect2, varscan2
- TNXB | c.12164G>A p.R4055Q (on ENST00000647633; = p.R3808Q on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs376486710; called by muse, mutect2, varscan2
- TRERF1 | c.2578A>T p.M860L | Missense Mutation (SNP) | VAF 61/191 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as COSV100550284; called by muse, mutect2, varscan2
- TRPM3 | c.1093G>A p.D365N (on ENST00000357533 / NM_001366142.2; = p.D210N on NM_020952.6) | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV62473292; called by muse, mutect2, varscan2
- UGGT2 | c.1596T>A p.D532E | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.339); catalogued as COSV65078401; called by muse, mutect2, varscan2
- USP7 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV61215489, COSV61217351; called by muse, mutect2, varscan2
- ZDBF2 | c.3023A>T p.H1008L | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV65629213; called by muse, mutect2, varscan2
- ZNF23 | c.759G>T p.Q253H | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs765355287, COSV61841585; called by muse, mutect2, varscan2
- ZNF574 | c.1539C>A p.H513Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55906480; called by muse, mutect2, varscan2
- CDIPT | c.475dup p.H159Pfs*4 | Frame Shift Ins (INS) | VAF 40/148 reads (27%) | called by mutect2, pindel, varscan2
- CENPS-CORT | c.179_199del p.X60_splice | Splice Site (DEL) | VAF 26/290 reads (9%) | called by mutect2, pindel
- ITGB3BP | c.28del p.D10Mfs*4 | Frame Shift Del (DEL) | VAF 88/260 reads (34%) | called by mutect2, pindel, varscan2
- LNX1 | c.42_43del p.A15Sfs*22 | Frame Shift Del (DEL) | VAF 31/108 reads (29%) | called by pindel, varscan2
- RBP3 | c.633G>C p.W211C | Missense Mutation (SNP) | VAF 115/413 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF43 | c.134_147del p.K45Sfs*25 | Frame Shift Del (DEL) | VAF 28/68 reads (41%) | called by mutect2, pindel, varscan2
- SLC27A3 | c.238_249delinsAGTG p.V80Sfs*138 | Frame Shift Del (DEL) | VAF 29/89 reads (33%) | called by pindel, varscan2*
- TRIM46 | c.1884_1886+10del p.X628_splice | Splice Site (DEL) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- WASHC2C | c.3842C>A p.S1281Y (on ENST00000336378; = p.S1260Y on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/1022 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2
- ZNF772 | c.214dup p.M72Nfs*12 | Frame Shift Ins (INS) | VAF 19/78 reads (24%) | called by mutect2, pindel, varscan2
- ABCB11 | c.729G>A p.L243= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs895814774, COSV55598595; called by muse, mutect2, varscan2
- BCL7B | c.123G>A p.T41= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as rs782348963, COSV56271211; called by muse, mutect2, varscan2
- CREB3L3 | c.954C>T p.A318= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV50254930; called by muse, mutect2, varscan2
- CRP | c.375G>A p.V125= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV54814418; called by muse, mutect2, varscan2
- DCUN1D2 | c.540G>C p.A180= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV60261877, COSV60262342; called by muse, mutect2, varscan2
- FSCN1 | c.897C>T p.D299= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100435097; called by muse, mutect2, varscan2
- GRINA | c.270A>C p.P90= | Silent (SNP) | VAF 46/139 reads (33%) | catalogued as rs1045718543, COSV100507266; called by muse, mutect2, varscan2
- GZMK | c.675C>T p.H225= | Silent (SNP) | VAF 66/150 reads (44%) | catalogued as rs563658216, COSV50247389; called by muse, mutect2, varscan2
- ICAM5 | c.798G>A p.L266= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV55748861; called by muse, mutect2, varscan2
- IL31RA | c.1866C>T p.D622= | Silent (SNP) | VAF 55/121 reads (45%) | catalogued as COSV61696439; called by muse, mutect2, varscan2
- KANK2 | c.1989C>T p.A663= (on ENST00000586659 / NM_001379562.1; = p.A671= on NM_015493.7 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as rs539680470, COSV100763232, COSV62009595; called by muse, mutect2, varscan2
- KDR | c.3102C>T p.I1034= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV55773824; called by muse, mutect2, varscan2
- LAMA5 | c.4962G>A p.V1654= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV53369978; called by muse, mutect2, varscan2
- LIMCH1 | c.1482G>A p.L494= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as COSV58293990; called by muse, mutect2, varscan2
- LMLN | c.699C>T p.A233= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as rs1420054536, COSV57604328; called by muse, mutect2, varscan2
- MAB21L1 | c.198C>T p.L66= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV59774989, COSV59822046; called by muse, mutect2, varscan2
- MAGI2 | c.2089C>A p.R697= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as COSV62653795, COSV62690947; called by muse, mutect2, varscan2
- MDN1 | c.33G>T p.A11= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV65528647; called by muse, mutect2, varscan2
- MPIG6B | c.162G>A p.K54= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV65390237; called by muse, mutect2, varscan2
- NSMAF | c.786T>C p.D262= | Silent (SNP) | VAF 44/156 reads (28%) | catalogued as COSV50687604, COSV50698049; called by muse, mutect2, varscan2
- OR2F2 | c.378G>T p.V126= | Silent (SNP) | VAF 53/187 reads (28%) | catalogued as COSV101283804; called by muse, mutect2, varscan2
- PANX2 | c.654C>T p.G218= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV50309330; called by muse, mutect2, varscan2
- PEX1 | c.900G>A p.A300= | Silent (SNP) | VAF 41/143 reads (29%) | catalogued as rs372013709; called by muse, mutect2, varscan2
- SOCS2 | c.345G>A p.K115= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV61392543; called by muse, mutect2, varscan2
- TENM1 | c.4335C>T p.D1445= | Silent (SNP) | VAF 70/114 reads (61%) | catalogued as rs371785558, COSV64440669; called by muse, mutect2, varscan2
- TMTC1 | c.606C>A p.P202= (on ENST00000539277 / NM_001193451.2; = p.P94= on NM_175861.3) | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV55491541; called by muse, mutect2, varscan2
- TNK1 | c.543G>A p.L181= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV61172146; called by muse, mutect2, varscan2
- TRERF1 | c.2577G>C p.V859= | Silent (SNP) | VAF 62/192 reads (32%) | catalogued as COSV100550201, COSV61676851; called by muse, mutect2, varscan2
- TRIP10 | c.567A>G p.E189= | Silent (SNP) | VAF 39/131 reads (30%) | catalogued as COSV57574830; called by muse, mutect2, varscan2
- VPS4A | c.147C>T p.S49= | Silent (SNP) | VAF 46/149 reads (31%) | catalogued as rs746250461, COSV54751922; called by muse, mutect2, varscan2
- ZMYM1 | c.219G>A p.V73= | Silent (SNP) | VAF 83/211 reads (39%) | catalogued as COSV63253321; called by muse, mutect2, varscan2
- ZNF574 | c.1540C>T p.L514= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs778371184, COSV55906492, COSV99725688; called by muse, mutect2, varscan2
- HLA-L | n.495_501del | RNA (DEL) | VAF 30/114 reads (26%) | called by mutect2, pindel, varscan2
